Somatic mutation profile of tumor specimen TCGA-J4-AATV-01A (aliquot TCGA-J4-AATV-01A-11D-A41K-08) from TCGA case TCGA-J4-AATV, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.0 years (25,943 days).
Specimen TCGA-J4-AATV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a08e8c90-5642-4aa4-82d3-e3b4c2d0a454.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-AATV-10A (Blood Derived Normal), aliquot TCGA-J4-AATV-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b557f50-4533-4426-ae93-0ad93f28602f

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Missense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1orf216 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99231131; called by muse, mutect2
- IKZF3 | c.62-2A>C p.X21_splice | Splice Site (SNP) | VAF 4/66 reads (6%) | catalogued as COSV99499815; called by muse, mutect2
- ZNF518A | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs1554885065, COSV100283585; called by muse, mutect2
